Somatic mutation profile of tumor specimen 0DOXH2 from CCDI case PBCCYZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 15.7 years (5,750 days).
Specimen 0DOXH2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7b9eb1a-417c-4c42-919a-9ede9302b510.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOXG2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bbfa078-a34a-4421-9199-da04a2059a28

The open-access MAF lists 127 somatic variants for this specimen: 89 protein-altering or splice-affecting, 23 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 23, Intron 8, Nonsense Mutation 5, 5'UTR 3, 3'UTR 3, Frame Shift Del 2, Frame Shift Ins 2, Splice Region 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 252/411 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADAM22 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 153/635 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs747003933; called by muse, mutect2, varscan2
- ADAM8 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.131); catalogued as rs371796178; called by mutect2, varscan2
- ADAMTS20 | c.4570C>T p.R1524* | Nonsense Mutation (SNP) | VAF 89/309 reads (29%) | catalogued as rs186549011, COSV101238834; called by muse, mutect2, varscan2
- APEX1 | c.796T>G p.F266V | Missense Mutation (SNP) | VAF 97/312 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99164535; called by muse, mutect2, varscan2
- ARHGAP6 | c.2452G>A p.A818T (on ENST00000337414 / NM_013427.3; = p.A615T on NM_013423.3) | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as rs1433070766; called by muse, mutect2, varscan2
- ARMC8 | c.1300G>T p.V434F (on ENST00000469044 / NM_001363941.2; = p.V420F on NM_015396.6) | Missense Mutation (SNP) | VAF 93/293 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs570676111; called by muse, mutect2, varscan2
- ARSB | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM940118; called by muse, mutect2, varscan2
- ATF7IP | c.1823G>C p.C608S | Missense Mutation (SNP) | VAF 109/366 reads (30%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as rs1477038668, COSV53776471; called by muse, mutect2, varscan2
- BCOR | c.3487C>T p.R1163* | Nonsense Mutation (SNP) | VAF 49/121 reads (40%) | catalogued as COSV60713352; called by muse, mutect2, varscan2
- COL11A1 | c.1635dup p.P546Afs*9 | Frame Shift Ins (INS) | VAF 92/309 reads (30%) | catalogued as rs779795373; called by mutect2, varscan2
- CREB3L2 | c.1182C>G p.F394L | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1400924900; called by muse, mutect2, varscan2
- DKK2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs866892165, COSV53394617, COSV53399664; called by muse, mutect2
- FLG2 | c.4009T>C p.S1337P | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1325374394; called by muse, mutect2, varscan2
- GULP1 | c.681C>G p.H227Q | Missense Mutation (SNP) | VAF 144/510 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs751559772; called by muse, mutect2, varscan2
- IQGAP2 | c.4232G>C p.R1411P | Missense Mutation (SNP) | VAF 114/536 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99059511; called by muse, mutect2, varscan2
- IQSEC2 | c.4033C>T p.R1345W | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.825); catalogued as rs1333401052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KARS1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs780320080; called by muse, mutect2, varscan2
- LAMB1 | c.4257C>G p.D1419E | Missense Mutation (SNP) | VAF 92/414 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55966042; called by muse, mutect2, varscan2
- MEF2D | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs551484443; called by muse, mutect2, varscan2
- MUC17 | c.7188C>A p.S2396R | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as rs752429220; called by muse, mutect2, varscan2
- OGT | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 102/289 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.79); catalogued as COSV65480426; called by muse, mutect2, varscan2
- PABPC5 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 81/318 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs775607627; called by muse, mutect2, varscan2
- PBK | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 120/1133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57273692; called by muse, mutect2, varscan2
- PCDHGA6 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as rs974732178, COSV99545373; called by muse, mutect2, varscan2
- PEPD | c.789C>G p.N263K | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54895654, COSV54895815; called by muse, mutect2, varscan2
- PPP1R3A | c.1508A>T p.E503V | Missense Mutation (SNP) | VAF 156/697 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV52882197; called by muse, mutect2, varscan2
- PROKR2 | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs755562438; called by muse, mutect2, varscan2
- PYHIN1 | c.724A>G p.T242A | Missense Mutation (SNP) | VAF 113/422 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63721981; called by muse, mutect2, varscan2
- RYR1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568522756; called by muse, mutect2, varscan2
- SF3A2 | c.1144G>C p.A382P | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1423523884; called by muse, varscan2
- SHROOM2 | c.2572G>T p.A858S | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs753343617; called by muse, mutect2, varscan2
- SLC45A2 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 113/453 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV56873482; called by muse, mutect2, varscan2
- SSTR1 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs756543872; called by muse, mutect2, varscan2
- TCEAL4 | c.620G>T p.R207M | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65463758; called by muse, mutect2, varscan2
- THOC7 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 127/468 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766459807, COSV55732882; called by muse, mutect2, varscan2
- WDFY3 | c.8309G>A p.R2770Q | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560564400; called by mutect2, varscan2
- ZNF653 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs1247689060, COSV53402467; called by muse, mutect2, varscan2
- ARID1A | c.326_353del p.P109Rfs*114 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | called by mutect2, varscan2
- ARL13A | c.676T>G p.S226A | Missense Mutation (SNP) | VAF 94/320 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- BASP1 | c.620A>T p.E207V | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- BPNT2 | c.278_280dup p.K93_S94ins* | Nonsense Mutation (INS) | VAF 32/245 reads (13%) | called by mutect2, varscan2
- CACNG8 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CCDC71L | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- CD1B | c.985T>C p.Y329H | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- CHADL | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CNGB3 | c.1581T>C p.G527= | Splice Region (SNP) | VAF 75/667 reads (11%) | called by muse, mutect2, varscan2
- CNKSR2 | c.3022G>T p.D1008Y | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- COL4A6 | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKD | c.2763G>C p.W921C (on ENST00000264057 / NM_152879.3; = p.W877C on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK5 | c.4418A>G p.K1473R | Missense Mutation (SNP) | VAF 79/493 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- DYNC2H1 | c.5519T>G p.V1840G | Missense Mutation (SNP) | VAF 120/537 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EML1 | c.2011C>G p.H671D | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- F5 | c.3166T>G p.Y1056D | Missense Mutation (SNP) | VAF 106/368 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM135B | c.3551T>C p.F1184S | Missense Mutation (SNP) | VAF 74/713 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR50 | c.993G>C p.E331D | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- IRF6 | c.967T>C p.W323R | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNA6 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT20 | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- MATK | c.1204A>T p.T402S (on ENST00000310132 / NM_139355.3; = p.T403S on NM_002378.4) | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- METAP2 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 94/325 reads (29%) | called by muse, mutect2, varscan2
- MOCOS | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NBEAL1 | c.2693A>G p.E898G | Missense Mutation (SNP) | VAF 147/516 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- NUP210 | c.1723G>C p.D575H | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP88 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OPN1LW | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2B2 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR4K15 | c.559A>C p.T187P (on ENST00000305051; = p.T163P on NM_001005486.1) | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2
- POP1 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 125/876 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PPFIA2 | c.2597G>A p.G866D | Missense Mutation (SNP) | VAF 159/537 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PPP1R15B | c.2059T>A p.L687M | Missense Mutation (SNP) | VAF 133/709 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRDM8 | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- RNF149 | c.829A>C p.K277Q | Missense Mutation (SNP) | VAF 129/425 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- RPGRIP1L | c.896T>C p.L299P | Missense Mutation (SNP) | VAF 151/330 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SBNO2 | c.3295G>T p.G1099C | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SIM2 | c.1907T>G p.L636R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SLC4A5 | c.3067G>T p.V1023L | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SLC6A12 | c.118A>C p.T40P | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- SNRNP70 | c.1304_1309del p.A435_P436del | In Frame Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, varscan2
- TAS2R3 | c.633_634dup p.R212Hfs*41 | Frame Shift Ins (INS) | VAF 23/87 reads (26%) | called by mutect2, varscan2
- TEX13A | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEX13D | c.1893del p.L633Wfs*28 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | called by mutect2, varscan2
- TEX13D | c.1894C>A p.P632T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.535); called by mutect2, varscan2
- THBS4 | c.1265G>T p.R422I | Missense Mutation (SNP) | VAF 93/376 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC6 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- USHBP1 | c.1385T>A p.V462E | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- XPNPEP2 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF404 | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ZPBP | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 92/502 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, varscan2
- ADRA2A | c.1014G>A p.A338= | Silent (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- AZGP1 | c.516A>T p.P172= | Silent (SNP) | VAF 51/234 reads (22%) | catalogued as rs754902099; called by muse, mutect2, varscan2
- BRPF1 | c.162A>G p.Q54= | Silent (SNP) | VAF 54/172 reads (31%) | called by muse, mutect2, varscan2
- CNIH3 | c.375C>T p.A125= | Silent (SNP) | VAF 73/214 reads (34%) | catalogued as rs957414210, COSV99685544; called by mutect2, varscan2
- COL4A5 | c.2193A>G p.G731= | Silent (SNP) | VAF 89/301 reads (30%) | called by muse, mutect2, varscan2
- CPN2 | c.834G>A p.R278= | Silent (SNP) | VAF 76/226 reads (34%) | called by muse, mutect2, varscan2
- CSH1 | c.402C>T p.S134= | Silent (SNP) | VAF 48/149 reads (32%) | catalogued as rs774390229, COSV60242945; called by muse, mutect2, varscan2
- CSNK2A1 | c.24G>A p.R8= | Silent (SNP) | VAF 39/201 reads (19%) | called by muse, mutect2, varscan2
- DFFB | c.198C>T p.N66= | Silent (SNP) | VAF 83/282 reads (29%) | catalogued as rs1399478611, COSV58214997; called by muse, mutect2, varscan2
- E2F5 | c.1035T>C p.N345= | Silent (SNP) | VAF 138/1027 reads (13%) | catalogued as rs772507869; called by muse, mutect2, varscan2
- GPC4 | c.258G>T p.V86= | Silent (SNP) | VAF 99/354 reads (28%) | catalogued as COSV63700284; called by muse, mutect2, varscan2
- HDAC4 | c.972G>A p.P324= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as rs138685594; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.6561C>T p.G2187= | Silent (SNP) | VAF 84/265 reads (32%) | called by muse, mutect2, varscan2
- NXPE3 | c.822C>T p.T274= | Silent (SNP) | VAF 63/229 reads (28%) | catalogued as rs201844634, COSV99840077; called by muse, mutect2, varscan2
- OR2T33 | c.867T>C p.S289= | Silent (SNP) | VAF 128/462 reads (28%) | called by muse, varscan2
- PCDHA3 | c.1053T>C p.V351= | Silent (SNP) | VAF 55/361 reads (15%) | called by muse, mutect2, varscan2
- PCDHB1 | c.2226A>G p.Q742= | Silent (SNP) | VAF 103/430 reads (24%) | called by muse, mutect2, varscan2
- PPP1R15B | c.2061G>A p.L687= | Silent (SNP) | VAF 136/713 reads (19%) | called by muse, mutect2
- RANBP17 | c.2241G>A p.T747= | Silent (SNP) | VAF 107/429 reads (25%) | catalogued as rs769532187; called by muse, mutect2, varscan2
- SERPINI1 | c.234T>C p.Y78= | Silent (SNP) | VAF 71/265 reads (27%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.1131A>G p.A377= | Silent (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- TAF7L | c.144C>T p.D48= | Silent (SNP) | VAF 58/187 reads (31%) | called by muse, mutect2, varscan2
- TRIML1 | c.285C>T p.Y95= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as rs773005360, COSV60195886; called by muse, mutect2, varscan2
- ABCB6 | c.1719+56C>T | Intron (SNP) | VAF 49/136 reads (36%) | catalogued as rs1265737881; called by muse, mutect2, varscan2
- BTBD16 | c.-2T>G | 5'UTR (SNP) | VAF 115/280 reads (41%) | called by muse, mutect2, varscan2
- DEFA5 | c.*26T>A | 3'UTR (SNP) | VAF 26/158 reads (16%) | called by mutect2, varscan2
- DMD | c.*33A>C | 3'UTR (SNP) | VAF 141/510 reads (28%) | called by muse, mutect2, varscan2
- FKBP9 | c.-85C>G | 5'UTR (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2, varscan2
- HEMGN | c.-14G>T | 5'UTR (SNP) | VAF 33/87 reads (38%) | catalogued as COSV99412244; called by muse, mutect2, varscan2
- MAPRE2 | c.*81T>C | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- PSMD9 | c.454-25T>G | Intron (SNP) | VAF 52/214 reads (24%) | called by muse, mutect2, varscan2
- SPAG17 | c.315+38T>C | Intron (SNP) | VAF 129/203 reads (64%) | called by muse, mutect2, varscan2
- SSRP1 | c.1482-52G>A | Intron (SNP) | VAF 26/77 reads (34%) | catalogued as rs770905540; called by muse, mutect2, varscan2
- TBC1D8B | c.131-86A>T | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2
- VIPR1 | c.790+21T>C | Intron (SNP) | VAF 39/158 reads (25%) | called by muse, mutect2, varscan2
- WASHC2C | c.2812-75T>G | Intron (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1203G>C | Intron (SNP) | VAF 122/409 reads (30%) | catalogued as COSV101268137; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451452 C>T | 5'Flank (SNP) | VAF 38/180 reads (21%) | called by muse, mutect2, varscan2
